Somatic mutation profile of tumor specimen TARGET-10-PARKFU-09A (aliquot TARGET-10-PARKFU-09A-01D) from TARGET case TARGET-10-PARKFU, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 15.1 years (5,519 days).
Specimen TARGET-10-PARKFU-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 13d53980-71a2-41c2-88bb-965720927431.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARKFU-10A (Blood Derived Normal), aliquot TARGET-10-PARKFU-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/902e24b7-69cb-4489-b2b6-ebdf66f9dfe2

The open-access MAF lists 35 somatic variants for this specimen: 20 protein-altering or splice-affecting, 6 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 6, Intron 4, 3'UTR 3, 5'UTR 2, Nonsense Mutation 1, In Frame Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 12/79 reads (15%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PAX5 | c.77T>G p.V26G | Missense Mutation (SNP) | VAF 20/104 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs926053251, COSV63904854, COSV63909409; called by muse, varscan2
- ALDH18A1 | c.1109C>T p.A370V | Missense Mutation (SNP) | VAF 3/50 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.173); catalogued as rs1320690165, COSV100973180; ClinVar: uncertain significance; called by muse, mutect2
- DNAH10 | c.5677G>A p.G1893S (on ENST00000409039; = p.G1832S on NM_207437.3) | Missense Mutation (SNP) | VAF 27/110 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768459284, COSV68987919; called by muse, mutect2, varscan2
- ELF5 | c.376C>T p.R126C (on ENST00000312319 / NM_198381.2; = p.R116C on NM_001422.4) | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs766657108; called by muse, mutect2, varscan2
- GPR83 | c.7C>T p.P3S | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as rs1249921074; called by muse, mutect2, varscan2
- KIFC1 | c.629G>A p.R210H | Missense Mutation (SNP) | VAF 61/161 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.247); catalogued as rs773177817, COSV65737969; called by muse, mutect2, varscan2
- NEK10 | c.2431C>T p.R811C | Missense Mutation (SNP) | VAF 51/115 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs774551711, COSV55356403, COSV99834621; called by muse, mutect2, varscan2
- OR13C2 | c.242C>T p.T81M | Missense Mutation (SNP) | VAF 74/147 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs370289806; called by muse, mutect2, varscan2
- TDRD5 | c.1631G>A p.R544Q | Missense Mutation (SNP) | VAF 49/112 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54240036, COSV54244565; called by muse, mutect2, varscan2
- TMEM132D | c.2165C>T p.P722L | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1220855662; called by muse, mutect2, varscan2
- ADGRE5 | c.1673_1674insTCG p.S558_L559insR (on ENST00000242786 / NM_078481.4; = p.S465_L466insR on NM_001784.5) | In Frame Ins (INS) | VAF 17/41 reads (41%) | called by mutect2, pindel, varscan2
- AKNA | c.657G>A p.W219* | Nonsense Mutation (SNP) | VAF 54/138 reads (39%) | called by muse, mutect2, varscan2
- CDC42BPA | c.812G>A p.C271Y | Missense Mutation (SNP) | VAF 18/141 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CLK2 | c.1145A>G p.Q382R (on ENST00000368361 / NM_001294339.2; = p.Q381R on NM_003993.4) | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- GOLM1 | c.904G>T p.V302L | Missense Mutation (SNP) | VAF 38/84 reads (45%) | SIFT tolerated (0.38); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IGLV2-8 | c.350_353delinsCCC p.N117Tfs*? | Frame Shift Del (DEL) | VAF 56/108 reads (52%) | called by pindel, varscan2*
- NEFL | c.910G>A p.E304K | Missense Mutation (SNP) | VAF 25/124 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- PUM1 | c.1126G>A p.V376M | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated, low confidence (0.18); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- TPBG | c.983A>T p.K328I | Missense Mutation (SNP) | VAF 39/77 reads (51%) | SIFT deleterious (0.05); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- CHRNB4 | c.657C>T p.Y219= | Silent (SNP) | VAF 55/120 reads (46%) | catalogued as rs762292972, COSV55715846; called by muse, mutect2, varscan2
- DDR2 | c.2559C>T p.G853= | Silent (SNP) | VAF 17/109 reads (16%) | catalogued as rs142174119; ClinVar: likely benign; called by muse, mutect2, varscan2
- IQSEC3 | c.3246G>A p.P1082= | Silent (SNP) | VAF 15/29 reads (52%) | catalogued as rs780137448, COSV100407807; called by muse, varscan2
- PCDH11X | c.2790C>T p.P930= | Silent (SNP) | VAF 50/112 reads (45%) | called by muse, mutect2, varscan2
- PROS1 | c.1236C>A p.P412= | Silent (SNP) | VAF 38/83 reads (46%) | catalogued as COSV67776685; called by muse, mutect2, varscan2
- SCN11A | c.5175C>T p.V1725= | Silent (SNP) | VAF 16/122 reads (13%) | catalogued as COSV56570509; called by muse, mutect2, varscan2
- ALDH1L1 | c.*142C>T | 3'UTR (SNP) | VAF 6/13 reads (46%) | catalogued as rs547743316; called by muse, varscan2
- CASTOR1 | c.506-48G>C | Intron (SNP) | VAF 34/72 reads (47%) | called by muse, mutect2, varscan2
- DST | c.1239+80G>A | Intron (SNP) | VAF 19/47 reads (40%) | called by muse, mutect2, varscan2
- MYORG | c.-28G>A | 5'UTR (SNP) | VAF 7/31 reads (23%) | catalogued as rs775660830; called by muse, varscan2
- NRG1 | c.502+31011C>T | Intron (SNP) | VAF 20/81 reads (25%) | catalogued as rs773794462, COSV55159461; called by muse, mutect2, varscan2
- PDHA2 | c.-33C>T | 5'UTR (SNP) | VAF 4/12 reads (33%) | catalogued as rs1471524163, COSV54777210; called by muse, mutect2
- PFN2 | c.*1295T>G | 3'UTR (SNP) | VAF 9/23 reads (39%) | called by muse, mutect2, varscan2
- RAD51 | c.*116C>T | 3'UTR (SNP) | VAF 12/30 reads (40%) | catalogued as rs541728912; called by muse, varscan2
- RPS11 | c.224-55T>C | Intron (SNP) | VAF 28/148 reads (19%) | called by muse, mutect2, varscan2
